Surgical pathology report (de-identified scan), TCGA case TCGA-FZ-5924, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-FZ-5924-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: HEAD OF PANCREAS AND PORTION OF SMALL BOWEL, PANCREATICODUODENECTOMY -

- A. INVASIVE, MODERATE-TO-POORLY DIFFERENTIATED DUCTAL ADENOCARCINOMA (3.2 CM), INVADING THROUGH THE DUODENAL WALL INTO THE SUBMUCOSA AND PERIPANCREATIC FAT.
- B. LYMPHOVASCULAR AND PERINEURAL INVASION ARE IDENTIFIED.
- C. TUMOR IS WITHIN 0.5 MM OF THE PANCREATIC MARGIN (see comment)
- D. TUMOR IS WITHIN 1.0 MM OF THE VASCULAR GROOVE RESECTION MARGIN.
- E. OTHER SURGICAL MARGINS ARE NEGATIVE FOR TUMOR.
- F. METASTATIC ADENOCARCINOMA TO TWO OUT OF EIGHTEEN LYMPH NODES (2/18).
- G. PATHOLOGIC STAGE pT3 N1 MX.

PART 2: GALLBLADDER, CHOLECYSTECTOMY - CHRONIC CHOLECYSTITIS.

COMMENT:

The permanent sections of the pancreatic margin contain abundant volume of tumor. The original frozen sections were reviewed. The second level of the frozen shows microscopic foci of neoplastic glands, although the first level is equivocal whether cancer is really present on the original frozen section. [REDACTED] have reviewed this case as a 5% pre-sign out QC review.

SYNOPTIC DATA - PRIMARY PANCREAS (EXOCRINE) TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Pylorus sparing pancreaticoduodenectomy, partial pancreatectomy
TUMOR SITE: Pancreatic head
TUMOR SIZE: Greatest dimension: 3.2 cm
Additional dimensions: 3 x 1.9 cm
OTHER ORGANS RESECTED: Gallbladder

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Ductal adenocarcinoma
HISTOLOGIC GRADE: G3
PATHOLOGIC STAGING (pTNM): pT3
pN1a
Number of lymph nodes examined: 18
Number of lymph nodes involved: 2
pMX
Treatment: Unknown
MARGINS: Common bile duct margin uninvolved
Pancreatic parenchymal margin uninvolved
MARGINS** (continued) Uncinate process/retroperitoneal margin uninvolved
Invasive neoplasm is within 2mm of inked SMV/portal vein notch margin
Proximal duodenal/gastric margin uninvolved
Distal duodenal margin uninvolved
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):
PERINEURAL INVASION: Present
ADDITIONAL PATHOLOGIC FINDINGS: Pancreatic intraepithelial neoplasia (highest grade: PanIN 3)

Source: NCI Genomic Data Commons file 66dd74da-a5c2-4478-af0c-875eb7b96cd3 (TCGA-FZ-5924.A405A1F0-F332-4E17-9706-C31664E7C8D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).